Somatic mutation profile of tumor specimen 0DI5FN from CCDI case PBBVHF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 13.9 years (5,074 days).
Specimen 0DI5FN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73881911-5f54-40e6-a32a-83f9b77bc812.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI5EH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/568bad2f-cf20-4a06-bc84-9d0e5d434d6e

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6AP2 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 393/1174 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as rs768989127, COSV65797125; ClinVar: uncertain significance; called by muse, varscan2
- FAM160A2 | c.1690C>T p.R564C (on ENST00000449352 / NM_001098794.2; = p.R578C on NM_032127.4) | Missense Mutation (SNP) | VAF 241/684 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.332); catalogued as rs146982586; called by muse, mutect2, varscan2
- KBTBD7 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 236/603 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs746817127; called by muse, mutect2, varscan2
- AR | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 18/654 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPC3 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 249/568 reads (44%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- AFF2 | c.1041+56418G>T | Intron (SNP) | VAF 454/1275 reads (36%) | called by muse, mutect2, varscan2
- CDK16 | c.-366G>C | 5'UTR (SNP) | VAF 39/114 reads (34%) | called by muse, mutect2, varscan2
